Somatic mutation profile of tumor specimen ALCH-B1TC-TTP1-A (aliquot ALCH-B1TC-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1TC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.8 years (26,580 days).
Specimen ALCH-B1TC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa21810b-59f3-42a3-af16-b3f07ac396d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TC-NB1-A (Blood Derived Normal), aliquot ALCH-B1TC-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6d6ae97-7e26-4a66-9ec0-d48138233ba2

The open-access MAF lists 208 somatic variants for this specimen: 141 protein-altering or splice-affecting, 39 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 39, Intron 12, Nonsense Mutation 7, 5'UTR 7, 3'UTR 3, Frame Shift Del 3, 3'Flank 3, RNA 2, Splice Site 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 98/793 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11204G>T p.G3735V | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71283541; called by muse, mutect2
- ADGRB3 | c.2597C>G p.P866R | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV99483595; called by muse, mutect2, varscan2
- ALPK2 | c.4294G>A p.E1432K | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs767336572, COSV64493224; called by muse, mutect2
- ANKLE2 | c.2409G>C p.L803F | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs572111545, COSV100514262; called by muse, mutect2, varscan2
- AR | c.676T>A p.L226I | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV65958505; called by muse, mutect2, varscan2
- ASTE1 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV53907928; called by muse, mutect2
- BRINP3 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.43); catalogued as rs1318975956, COSV66513173; called by muse, mutect2
- CDKN2A | c.213C>A p.N71K | Missense Mutation (SNP) | VAF 57/492 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as CD044135, CM980328, COSV58687044, COSV58695272, COSV58699200, COSV58713592, COSV58721900; called by muse, mutect2, varscan2
- COL4A2 | c.4291C>T p.R1431C | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs139124960, COSV64626395; called by muse, mutect2, varscan2
- CUL3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV52368214; called by muse, mutect2, varscan2
- DNAI4 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.243); catalogued as COSV64018602; called by muse, varscan2
- DNER | c.1345G>T p.G449W | Missense Mutation (SNP) | VAF 112/824 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV59159659; called by muse, mutect2, varscan2
- DTNB | c.1834G>T p.G612C | Missense Mutation (SNP) | VAF 33/447 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1345251855; called by muse, mutect2
- ERBB4 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 37/365 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53512374; called by muse, varscan2
- FANCD2 | c.2116C>G p.Q706E | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs147532349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDF5 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as CD972235; called by muse, varscan2
- ICE1 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1231495459; called by muse, mutect2
- IL4R | c.823G>C p.V275L | Missense Mutation (SNP) | VAF 43/447 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs115310233; called by muse, mutect2
- IRF2 | c.914G>T p.W305L | Missense Mutation (SNP) | VAF 75/562 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV66929024, COSV66930071; called by muse, mutect2, varscan2
- KCNQ3 | c.1999G>T p.A667S | Missense Mutation (SNP) | VAF 35/769 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV101195880; called by muse, mutect2
- KIR2DL1 | c.574C>A p.H192N | Missense Mutation (SNP) | VAF 86/626 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV52409308; called by muse, mutect2, varscan2
- LAMA1 | c.5216C>A p.P1739Q | Missense Mutation (SNP) | VAF 66/644 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs541601813; called by muse, mutect2, varscan2
- LCE1A | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs142668295; called by muse, mutect2
- LRGUK | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 35/400 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as COSV53642654; called by muse, mutect2
- MAN1B1 | c.1014dup p.L339Afs*18 | Frame Shift Ins (INS) | VAF 48/390 reads (12%) | catalogued as rs752359237; called by mutect2, varscan2
- NEIL3 | c.1448G>C p.G483A | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as rs879371299; called by muse, mutect2
- NLRP14 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 20/275 reads (7%) | catalogued as COSV55067026; called by muse, mutect2
- OLR1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100376413; called by muse, mutect2
- OR6C76 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 34/201 reads (17%) | catalogued as rs747017448; called by muse, mutect2, varscan2
- PDE5A | c.2248C>T p.H750Y | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs745794935; called by muse, mutect2, varscan2
- PHLPP1 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 30/566 reads (5%) | SIFT tolerated, low confidence (0.06); catalogued as rs1189219428; called by muse, mutect2
- PRSS1 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 58/722 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs1157690064; called by muse, mutect2
- PUS1 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 31/699 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1045133170, CM1512406; called by muse, mutect2
- RCOR2 | c.1024C>G p.Q342E | Missense Mutation (SNP) | VAF 31/506 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100036291; called by muse, mutect2
- SAMSN1 | c.402C>A p.S134R | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53477967, COSV99582483; called by muse, mutect2, varscan2
- TRIB3 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs751952607, COSV53931777; called by muse, mutect2
- USP35 | c.1106G>T p.C369F | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1220926692; called by muse, mutect2
- YDJC | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1283843278; called by muse, mutect2
- ZFHX3 | c.4645G>A p.V1549I | Missense Mutation (SNP) | VAF 38/704 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.746); catalogued as rs181722888; called by muse, mutect2
- ZMYND11 | c.1392G>C p.Q464H | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.898); catalogued as COSV100556016; called by muse, mutect2, varscan2
- ZNF655 | c.964C>A p.Q322K | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV53160073; called by muse, mutect2
- ZNF804B | c.1504G>C p.G502R | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100305471; called by muse, mutect2
- ADAM12 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- AFP | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ARHGEF33 | c.1148A>T p.E383V | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ARID1A | c.4220del p.P1407Qfs*74 | Frame Shift Del (DEL) | VAF 31/242 reads (13%) | called by mutect2, pindel, varscan2
- ARNT2 | c.1655C>G p.S552C | Missense Mutation (SNP) | VAF 58/562 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2
- ASAP2 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASIC4 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- BMP1 | c.1256G>A p.S419N | Missense Mutation (SNP) | VAF 47/372 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- CAPN2 | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 20/498 reads (4%) | called by muse, mutect2
- CAPRIN2 | c.1320A>T p.E440D | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC168 | c.11255G>T p.G3752V | Missense Mutation (SNP) | VAF 27/357 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.111); called by muse, mutect2
- CEP192 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.115); called by muse, mutect2
- CFAP47 | c.7805A>G p.Q2602R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.191); called by muse, mutect2
- CHAC1 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 59/574 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CHCHD2 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.047); called by muse, mutect2
- CHGB | c.1802A>G p.Y601C | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CHTF18 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL19A1 | c.3083G>A p.R1028K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- COL4A3 | c.1841G>C p.G614A | Missense Mutation (SNP) | VAF 54/786 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A6 | c.2788A>G p.N930D | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- CSMD3 | c.865del p.E289Kfs*7 | Frame Shift Del (DEL) | VAF 29/237 reads (12%) | called by mutect2, pindel, varscan2
- CTBP2 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- CWC22 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 17/197 reads (9%) | called by muse, mutect2
- DTD2 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.052); called by muse, mutect2
- EMILIN1 | c.1034T>A p.V345E | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- EOGT | c.1569A>T p.K523N (on ENST00000383701 / NM_001278689.2; = p.K439N on NM_173654.3) | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPG5 | c.5397G>C p.W1799C | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ERBB4 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EREG | c.98C>A p.T33K | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- F8 | c.3065C>T p.T1022I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FAM47B | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FGD4 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FUT4 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 47/506 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); called by muse, mutect2
- GABRG2 | c.1229A>T p.D410V (on ENST00000361925 / NM_001375343.1; = p.D370V on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/512 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GALNT3 | c.1093G>T p.G365* | Nonsense Mutation (SNP) | VAF 30/196 reads (15%) | called by muse, varscan2
- GATA2 | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- GIMAP6 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 124/917 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- GPR19 | c.1081A>C p.T361P | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIN3A | c.1163A>G p.Y388C | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); called by muse, mutect2
- GRK3 | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.315); called by muse, mutect2
- GTSF1L | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 30/361 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); called by muse, mutect2
- HBB | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 78/802 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- HCRTR2 | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 60/545 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HIRIP3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- IGKV2D-40 | c.16+2T>G p.X6_splice | Splice Site (SNP) | VAF 58/974 reads (6%) | called by muse, mutect2
- ITGA5 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ITPRID2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 29/732 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LILRB5 | c.1208C>G p.P403R | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LIMS2 | c.509G>A p.G170E (on ENST00000355119 / NM_001161403.3; = p.G194E on NM_017980.4) | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBD1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 99/964 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MON2 | c.1201T>C p.F401L | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2
- MRPS22 | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 58/680 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.615); called by muse, mutect2
- MRPS27 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH3 | c.1783C>G p.L595V | Missense Mutation (SNP) | VAF 75/646 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MYH8 | c.1142C>G p.T381R | Missense Mutation (SNP) | VAF 70/610 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NCBP2L | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- NMI | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- PAPPA2 | c.388del p.V130* | Frame Shift Del (DEL) | VAF 52/327 reads (16%) | called by mutect2, pindel, varscan2
- PCARE | c.3518C>T p.A1173V | Missense Mutation (SNP) | VAF 112/737 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHA10 | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.262); called by muse, mutect2
- PCDHA12 | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 79/746 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA5 | c.1342A>C p.N448H | Missense Mutation (SNP) | VAF 34/721 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PDCL2 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE4DIP | c.1199T>C p.L400S | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIF1 | c.601C>G p.P201A | Missense Mutation (SNP) | VAF 47/800 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- PLXNA4 | c.4987C>A p.Q1663K | Missense Mutation (SNP) | VAF 41/965 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2
- POU4F2 | c.1148A>T p.D383V | Missense Mutation (SNP) | VAF 42/373 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PPFIBP1 | c.270+5G>T | Splice Region (SNP) | VAF 37/332 reads (11%) | called by muse, mutect2, varscan2
- PRKRA | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 50/820 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRN2 | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- PTPRO | c.2126G>C p.R709T | Missense Mutation (SNP) | VAF 141/634 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAVER2 | c.354C>G p.N118K | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, varscan2
- RELN | c.4936G>T p.G1646* | Nonsense Mutation (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2
- RILPL1 | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 46/556 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by muse, mutect2
- RUBCN | c.2603C>A p.A868D | Missense Mutation (SNP) | VAF 50/630 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.331); called by muse, mutect2
- SCGN | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SEMA5B | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); called by muse, mutect2
- SERPINA11 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 60/601 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SETBP1 | c.2803A>G p.K935E | Missense Mutation (SNP) | VAF 62/582 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC6A12 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 126/840 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- SLC9A6 | c.1983A>T p.L661F | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SND1 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 50/520 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SORCS1 | c.1660T>A p.S554T | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- STARD13 | c.1678G>A p.E560K (on ENST00000336934 / NM_001243476.3; = p.E442K on NM_052851.3) | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SUPT6H | c.3628A>C p.S1210R | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- SYCE1 | c.1055G>C p.*352Sext*3 | Nonstop Mutation (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- TDRD15 | c.725C>A p.T242N | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- TENM2 | c.8270C>G p.A2757G (on ENST00000518659 / NM_001122679.2; = p.A2518G on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TKTL2 | c.1603G>T p.V535F | Missense Mutation (SNP) | VAF 37/397 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TPO | c.2282G>C p.R761T | Missense Mutation (SNP) | VAF 184/972 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TRIM37 | c.1282A>G p.S428G | Missense Mutation (SNP) | VAF 45/434 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- TTN | c.98408C>T p.S32803F (on ENST00000591111; = p.S25379F on NM_003319.4) | Missense Mutation (SNP) | VAF 49/230 reads (21%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP38 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR27 | c.2675C>G p.S892C | Missense Mutation (SNP) | VAF 21/245 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by muse, mutect2
- ZBED5 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF337 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- ZNF91 | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRB3 | c.777C>G p.A259= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- ALKBH8 | c.1293T>C p.G431= | Silent (SNP) | VAF 17/202 reads (8%) | called by muse, mutect2
- ANKAR | c.1782T>A p.A594= | Silent (SNP) | VAF 80/424 reads (19%) | called by muse, mutect2, varscan2
- ASAP2 | c.1176G>T p.L392= | Silent (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- ATP4A | c.312G>T p.A104= | Silent (SNP) | VAF 62/474 reads (13%) | called by muse, mutect2, varscan2
- CDK5R1 | c.186G>A p.K62= | Silent (SNP) | VAF 48/498 reads (10%) | called by muse, mutect2
- CENPC | c.255A>T p.S85= | Silent (SNP) | VAF 19/158 reads (12%) | called by muse, mutect2, varscan2
- CNDP2 | c.321G>T p.L107= | Silent (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- COL11A1 | c.3879A>T p.P1293= | Silent (SNP) | VAF 54/547 reads (10%) | called by muse, mutect2, varscan2
- COL6A3 | c.5544C>T p.D1848= | Silent (SNP) | VAF 38/326 reads (12%) | catalogued as COSV55091689; called by muse, mutect2, varscan2
- CWC22 | c.1041C>T p.F347= | Silent (SNP) | VAF 34/490 reads (7%) | catalogued as COSV55431689; called by muse, mutect2
- DISP2 | c.2940C>A p.L980= | Silent (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- EXOSC9 | c.105C>T p.I35= | Silent (SNP) | VAF 34/410 reads (8%) | catalogued as rs144563945; called by muse, mutect2
- FAM187B | c.561G>T p.V187= | Silent (SNP) | VAF 40/284 reads (14%) | called by muse, mutect2, varscan2
- FAM43A | c.102G>C p.A34= | Silent (SNP) | VAF 88/314 reads (28%) | called by muse, mutect2, varscan2
- FBXL2 | c.570G>A p.R190= | Silent (SNP) | VAF 55/359 reads (15%) | called by muse, mutect2, varscan2
- FGD4 | c.216A>T p.P72= | Silent (SNP) | VAF 61/471 reads (13%) | called by muse, mutect2, varscan2
- GDF5 | c.84C>T p.A28= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as rs549803995; called by muse, varscan2
- HIRIP3 | c.1137G>A p.Q379= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1029292458, COSV54231425; called by mutect2, varscan2
- HOXC8 | c.282C>A p.L94= | Silent (SNP) | VAF 44/814 reads (5%) | called by muse, mutect2
- HS3ST4 | c.1107C>T p.A369= | Silent (SNP) | VAF 45/382 reads (12%) | called by muse, mutect2, varscan2
- ITPR3 | c.5757G>A p.T1919= | Silent (SNP) | VAF 85/631 reads (13%) | catalogued as rs774632774; called by muse, mutect2, varscan2
- MOSPD1 | c.435G>A p.Q145= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1306188138, COSV66189700; called by muse, mutect2, varscan2
- OR51D1 | c.258C>G p.L86= | Silent (SNP) | VAF 42/438 reads (10%) | catalogued as rs753045991; called by muse, mutect2
- OR56A4 | c.915C>T p.F305= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- OR8J1 | c.90C>A p.V30= | Silent (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2, varscan2
- PARP4 | c.1650C>T p.V550= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1234513719; called by muse, mutect2, varscan2
- PLXNB2 | c.4272C>T p.L1424= | Silent (SNP) | VAF 34/370 reads (9%) | catalogued as rs751630630, COSV63781089, COSV63783418; called by muse, mutect2
- PRKD3 | c.1665A>T p.T555= | Silent (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- RBPJL | c.225G>A p.K75= | Silent (SNP) | VAF 45/416 reads (11%) | catalogued as COSV59214241; called by muse, mutect2, varscan2
- SEC24C | c.1374C>T p.P458= | Silent (SNP) | VAF 26/116 reads (22%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.957C>T p.A319= | Silent (SNP) | VAF 49/458 reads (11%) | catalogued as rs151296508; called by muse, mutect2, varscan2
- SRD5A1 | c.489G>A p.L163= | Silent (SNP) | VAF 17/168 reads (10%) | catalogued as COSV57013330, COSV57014523; called by muse, mutect2
- STAT5B | c.6T>G p.A2= | Silent (SNP) | VAF 29/321 reads (9%) | called by muse, mutect2
- TBCD | c.1680G>A p.T560= | Silent (SNP) | VAF 64/470 reads (14%) | catalogued as rs373657801, COSV62803833; called by muse, mutect2, varscan2
- TMEM63C | c.402G>T p.V134= | Silent (SNP) | VAF 51/501 reads (10%) | called by muse, mutect2
- ZBED9 | c.435A>G p.T145= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as rs1382961049, COSV101509354; called by muse, mutect2
- ZFPL1 | c.879C>T p.S293= | Silent (SNP) | VAF 34/492 reads (7%) | catalogued as rs143603280; called by muse, mutect2
- ZNF516 | c.3207T>C p.F1069= | Silent (SNP) | VAF 16/269 reads (6%) | called by muse, mutect2
- AK2 | chr1:33008488 C>A | 3'Flank (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- ARRB1 | c.21-13610G>T | Intron (SNP) | VAF 40/544 reads (7%) | called by muse, mutect2
- BBS1 | c.831-310T>G | Intron (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- CRHR1 | chr17:45784509 C>T | 5'Flank (SNP) | VAF 28/324 reads (9%) | called by muse, mutect2
- DENND2B | c.-25-6352G>C | Intron (SNP) | VAF 13/334 reads (4%) | called by muse, mutect2
- ETNPPL | c.411-15dup | Intron (INS) | VAF 21/131 reads (16%) | catalogued as rs767406209; called by mutect2, varscan2
- GPI | c.123-425A>G | Intron (SNP) | VAF 58/374 reads (16%) | called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.244C>T | RNA (SNP) | VAF 58/525 reads (11%) | called by muse, mutect2, varscan2
- IL15RA | c.-43C>T | 5'UTR (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44572078 C>A | 3'Flank (SNP) | VAF 30/694 reads (4%) | called by muse, mutect2
- LEUTX | c.-80G>T | 5'UTR (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- MKRN9P | n.571G>C | RNA (SNP) | VAF 22/492 reads (4%) | called by muse, mutect2
- MYO1F | c.3+74G>T | Intron (SNP) | VAF 29/204 reads (14%) | called by muse, mutect2, varscan2
- NOP56 | c.*97A>G | 3'UTR (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- NPAT | c.38-11101C>T | Intron (SNP) | VAF 29/265 reads (11%) | catalogued as rs994293817; called by muse, mutect2, varscan2
- OBSCN | c.11659+4348G>T | Intron (SNP) | VAF 161/775 reads (21%) | catalogued as COSV99472865; called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67533A>T | Intron (SNP) | VAF 40/438 reads (9%) | called by muse, mutect2
- PCK1 | c.1186+12C>T | Intron (SNP) | VAF 58/473 reads (12%) | called by muse, mutect2, varscan2
- PDZD7 | chr10:101015752 G>T | 3'Flank (SNP) | VAF 49/335 reads (15%) | called by muse, mutect2, varscan2
- RGPD1 | c.48+5869C>T | Intron (SNP) | VAF 36/664 reads (5%) | catalogued as COSV67962704; called by muse, mutect2
- SCNN1A | c.*5G>C | 3'UTR (SNP) | VAF 41/338 reads (12%) | catalogued as rs913130129; called by muse, mutect2, varscan2
- SERINC1 | c.-23G>T | 5'UTR (SNP) | VAF 14/312 reads (4%) | called by muse, mutect2
- SLC13A3 | c.-7C>T | 5'UTR (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
- STMP1 | c.-25C>T | 5'UTR (SNP) | VAF 26/269 reads (10%) | called by muse, mutect2, varscan2
- TNFRSF18 | c.*31A>T | 3'UTR (SNP) | VAF 44/306 reads (14%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.-35T>C | 5'UTR (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- TRPM4 | c.-16C>T | 5'UTR (SNP) | VAF 36/282 reads (13%) | catalogued as rs572530399; called by muse, mutect2, varscan2
- TTN | c.10360+3725C>A | Intron (SNP) | VAF 47/197 reads (24%) | catalogued as COSV60045218; called by muse, mutect2, varscan2
